Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7391, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7391-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) LYMPH NODE, LEFT POSTERIOR LEVEL 1, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).
- 2) LYMPH NODE, LEVEL 1, EXCISION: 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/4).
- 3) TONGUE, LEFT, PARTIAL GLOSSECTOMY: WELL-DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA, 1.0 CM IN GREATEST EXTENT, COMPLETELY EXCISED.
- 4) LYMPH NODES, LEFT NECK LEVEL 2, 3, 4, EXCISION: 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/4).
- 5) LYMPH NODES, ANTERIOR LEVEL 1, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

COMMENT: These findings correspond to AJCC (6TH edition) pathologic stage 1(pT1N0pM N/A).

Upper Aerodigestive Tract and Minor Salivary Glands Carcinoma

Summary of Findings:

Incisional and Excisional Biopsy, Resection

Note: Check 1 response unless otherwise indicated.

MACROSCOPIC

Specimen Type

☐ Incisional biopsy

☐ Excisional biopsy

☒ Resection (specify type): partial glossectomy

☐ Other (specify): _____

☐ Not specified

Tumor Site (check all that apply)

☐ Lip

☒ Oral cavity

☐ Pharynx, oropharynx

☐ Pharynx, hypopharynx

☐ Pharynx, nasopharynx

☐ Larynx, supraglottis

☐ Larynx, glottis

[page 2 of 5]
☐ Larynx, subglottis
☐ Paranasal sinus(es), maxillary
☐ Paranasal sinus(es), ethmoid
☐ Other (specify): _____
☐ Not specified

Tumor Size

Greatest dimension: 1.0 cm

*Additional dimensions: ____ x ____ cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

Histologic Grade

☐ Not applicable

☐ GX: Cannot be assessed

☒ G1: Well differentiated

G2: Moderately differentiated

☐ G3: Poorly differentiated

☐ Other (specify): _____

Pathologic Staging (pTNM) (see appropriate site below)

Note: The phrases in *italics* include clinical findings required for AJCC staging. This clinical information may be unknown to the pathologist. It is included here only for the sake of completeness.

Primary Tumor (pT): Lip and Oral Cavity

☐ pTX: Cannot be assessed

☐ pT0: No evidence of primary tumor

☐ pTis: Carcinoma in situ

☒ pT1: Tumor 2 cm or less in greatest dimension

☐ pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension

☐ pT3: Tumor more than 4 cm in greatest dimension

☐ pT4: Lip: Tumor invades through cortical bone, inferior alveolar nerve, floor of mouth, or skin of face, ie, chin or nose

☐ pT4a: Oral cavity: Tumor invades adjacent structures (eg, through cortical bone, into deep [extrinsic] muscle of tongue [genioglossus, hyoglossus, palatoglossus, and styloglossus], maxillary sinus, skin of face)

☐ pT4b: Tumor invades masticator space, pterygoid plates, or skull base, and/or encases internal carotid artery

*Extra-capsular Extension of Nodal Tumor

* ☒ Absent

* ☐ Present

* ☐ Indeterminate

Distant Metastasis (pM)

☒ pMX: Cannot be assessed

☐ pM1: Distant metastasis

[page 3 of 5]
*Specify site(s), if known: _____

Margins (check all that apply)

___ Cannot be assessed

X Margins uninvolved by tumor

Distance of tumor from closest margin: 1.2 cm

Specify margin, if possible: deep

___x Carcinoma in situ absent

___ Carcinoma in situ present

___ Carcinoma in situ, not applicable

___ Margin(s) involved by tumor

Specify margins(s), if possible: _____

___ Not applicable

*Venous/Lymphatic (Large/Small Vessel) Invasion (V/L)

* __x_ Absent

* ___ Present

* ___ Indeterminate

Perineural Invasion

___x_ Absent

___ Present

*Additional Pathologic Findings (check all that apply)

* ___ None identified

* ___ Carcinoma in situ

* x Inflammation (specify type): acute

* ___ Epithelial hyperplasia

* ___ Epithelial dysplasia

* ___ Other (specify): _____

*Comment(s)

Data elements with asterisks are not required for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management.

Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen

**Electronically

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. _____

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)posterior level 1 left neck; 2)level 1

lymph node; 3)left partial glossectomy;

4)left neck level 2, 3, 4; 5) anterior

[page 4 of 5]
GROSS DESCRIPTION:

1) SOURCE: Posterior Level 1 Left Neck

Received fresh for frozen section diagnosis in a container labeled "posterior level 1 left neck" are several fragments of fibrofatty tissue that in aggregate measure 1.4 x 1.0 x 0.5 cm. The tissue is palpated and one lymph node is identified. It is bisected and entirely submitted for frozen section diagnosis.

Summary of sections: 1AFSC, 2/1; 1B, remaining fatty tissue, M/1.

2) SOURCE: Level 1 Lymph Node

Received fresh for frozen section diagnosis in a container labeled "level 1 lymph node" is one fragment of fibrofatty tissue measuring 3.5 x 2.5 x 1.0 cm. The specimen is searched for lymph nodes and four possible lymph nodes are identified. They are all submitted for frozen section diagnosis.

Summary of sections: 2AFSC, 4/1.

3) SOURCE: Left Partial Glossectomy

Received fresh for frozen section diagnosis in a container labeled "left partial glossectomy, stitch on anterior margin" is one fragment of tongue measuring 3.0 x 2.3 cm and extending to a depth of 2.0 cm. The anterior margin is designated 12 o'clock and the specimen is inked as follows: 12 o'clock to 3 o'clock-blue, 3 o'clock to 6 o'clock-black, 6 o'clock to 9 o'clock-yellow, 9 o'clock to 12 o'clock-green. All of the margins are removed and submitted for frozen section diagnosis. The mucosal surface of the specimen contains a white, firm nodular lesion measuring 1.5 x 1.3 cm. A portion of this nodule is given to research. Serial sectioning of the specimen reveals that this nodule extends approximately 0.6 cm deep into the specimen and is approximately 1.0 cm from the deep surgical margin. Representative sections of the tumor of deep margin are submitted.

Summary of sections: 3AFSC, 12 to 3 o'clock, 1/1; 3BFSC, 3 to 6 o'clock, 1/1; 3CFSC, 6 to 9 o'clock, 1/1; 3DFSC, 9 to 12 o'clock, 1/1; 3E, 3F, representative sections of tumor in deep margin, 1/1 each.

4) SOURCE: Left Neck Levels 2,3 and 4

Received fresh in a container labeled "left neck levels 2, 3, 4" are several fragments of fibrofatty tissue that in aggregate measure 5.3 x 4.0 x 1.5 cm. The specimen is searched for lymph nodes and three possible lymph nodes are identified. One lymph node is bisected and submitted in 4A, 4B. One possible lymph node is bisected and submitted in 4C, one possible lymph node is bisected in 4D.

Summary of sections: 4A, 4B, 1/1 each; 4C, 2/1, 4D, 2/1.

5) SOURCE: Anterior Level 1

Received fresh in a container labeled "anterior level 1" is one fragment of fibrofatty tissue measuring 4.2 x 4.0 x 1.5 cm. The specimen is searched for lymph nodes and one possible lymph node is identified. The specimen is

[page 5 of 5]
bisected and submitted.

Summary of sections: 5A, 2/1.

Dictated by

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Posterior Level 1 Left Neck

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA.

2) SOURCE: Level One Lymph Node

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA.

3) SOURCE: Left Partial Glossectomy

FROZEN SECTION DIAGNOSIS: ALL LATERAL MARGINS NEGATIVE FOR CARCINOMA.

Electronically signed by: Attending Pathologist

Source: NCI Genomic Data Commons file fd79b621-4c4b-4031-9a8e-e3c54dad1fd3 (TCGA-CR-7391.EA47450E-0F35-45CF-AF2F-B982D59905FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).